Somatic mutation profile of tumor specimen C3N-02818-01 (aliquot CPT0384570009) from CPTAC case C3N-02818, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.9 years (25,175 days).
Specimen C3N-02818-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 489ef9dd-7bc3-4ce7-a446-8c3baa472af0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02818-31 (Blood Derived Normal), aliquot CPT0385440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2defeb8f-4bd0-424f-a8db-407052cd5927

The open-access MAF lists 105 somatic variants for this specimen: 67 protein-altering or splice-affecting, 17 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 17, Intron 12, Frame Shift Del 8, 3'UTR 5, Nonsense Mutation 4, 5'UTR 3, Frame Shift Ins 3, Splice Site 2, Splice Region 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTR1 | c.719A>T p.K240M | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62558468; called by muse, mutect2, varscan2
- APOB | c.13487G>C p.R4496T | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV51922834, COSV51952204, COSV51952606; called by muse, mutect2, varscan2
- CCDC47 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs376305681; called by muse, mutect2, varscan2
- CLCN6 | c.2042A>G p.Y681C | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs1288842100, COSV100411423; called by muse, mutect2, varscan2
- DHTKD1 | c.2482C>A p.H828N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.009); catalogued as COSV99536642; called by muse, mutect2, varscan2
- EBF2 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV68778168; called by muse, mutect2, varscan2
- EMX1 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.916); catalogued as COSV50689330, COSV50690077; called by muse, mutect2, varscan2
- FBN3 | c.5695C>T p.R1899* | Nonsense Mutation (SNP) | VAF 73/164 reads (45%) | catalogued as rs564282696; called by muse, mutect2, varscan2
- GABRG3 | c.1020T>A p.Y340* | Nonsense Mutation (SNP) | VAF 81/191 reads (42%) | catalogued as COSV100409575; called by muse, mutect2, varscan2
- HHLA1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs369994118; called by muse, mutect2, varscan2
- KRT4 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 163/327 reads (50%) | catalogued as rs1237497749, COSV53407579; called by muse, mutect2, varscan2
- LRRC24 | c.612C>G p.N204K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748390301, COSV99467184; called by muse, mutect2, varscan2
- PCDHA8 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.39); catalogued as COSV65337750; called by muse, mutect2, varscan2
- RAB3GAP1 | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs151096019; called by muse, mutect2, varscan2
- RP1 | c.3844C>G p.P1282A | Missense Mutation (SNP) | VAF 268/570 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV55111239; called by muse, mutect2, varscan2
- SETMAR | c.1013C>G p.T338S | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as rs149255014; called by muse, mutect2, varscan2
- WIF1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1194003320; called by muse, mutect2, varscan2
- ZNF780A | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as rs375366451; called by muse, mutect2, varscan2
- ZNF808 | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs747066303; called by muse, mutect2, varscan2
- AIFM3 | c.248T>G p.M83R | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALG1L | c.445del p.V149Cfs*18 | Frame Shift Del (DEL) | VAF 193/558 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD49 | c.276A>C p.R92S | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- BAZ2A | c.4828C>T p.H1610Y | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- C9orf43 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CASKIN1 | c.1601del p.I534Tfs*19 | Frame Shift Del (DEL) | VAF 126/461 reads (27%) | called by mutect2, pindel, varscan2
- CKLF-CMTM1 | c.211del p.M71* | Frame Shift Del (DEL) | VAF 70/260 reads (27%) | called by mutect2, pindel, varscan2
- CLCA2 | c.1165G>T p.D389Y | Missense Mutation (SNP) | VAF 102/219 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- COL4A5 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 125/135 reads (93%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COPG2 | c.2331dup p.D778Rfs*4 | Frame Shift Ins (INS) | VAF 142/384 reads (37%) | called by mutect2, pindel, varscan2
- CTSF | c.972G>C p.L324F | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DIP2C | c.3676G>C p.V1226L | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DIS3L2 | c.1697del p.L566Cfs*79 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | called by mutect2, pindel, varscan2
- DNAH3 | c.8025_8035del p.M2675Ifs*44 | Frame Shift Del (DEL) | VAF 175/336 reads (52%) | called by mutect2, pindel, varscan2
- DNAJC9 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EIF4G1 | c.3008A>G p.D1003G (on ENST00000346169 / NM_198241.3; = p.D808G on NM_004953.5) | Missense Mutation (SNP) | VAF 203/474 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GEMIN5 | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 165/368 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GID4 | c.576T>A p.D192E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.858); called by muse, mutect2
- GID4 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HORMAD1 | c.280-1G>A p.X94_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- INVS | c.1811_1814del p.K604Rfs*62 | Frame Shift Del (DEL) | VAF 148/387 reads (38%) | called by mutect2, pindel, varscan2
- LGI3 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRRC71 | c.98C>A p.A33E | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- MAGEA3 | c.104A>T p.E35V | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MFSD9 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORC2 | c.1481_1485del p.P494Hfs*26 (on ENST00000397641 / NM_001303256.3; = p.P432Hfs*26 on NM_014941.3) | Frame Shift Del (DEL) | VAF 59/135 reads (44%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.980_982del p.G327del (on ENST00000550270 / NM_206820.2; = p.G352del on NM_002465.4) | In Frame Del (DEL) | VAF 93/230 reads (40%) | called by mutect2, pindel, varscan2
- OR6T1 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 159/386 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2375C>T p.P792L (on ENST00000259318 / NM_001136562.3; = p.P1023L on NM_007203.5) | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA5 | c.453dup p.L152Vfs*36 | Frame Shift Ins (INS) | VAF 120/314 reads (38%) | called by mutect2, pindel, varscan2
- PCK2 | c.916T>A p.C306S | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD2 | c.2524C>T p.L842= | Splice Region (SNP) | VAF 166/634 reads (26%) | called by muse, varscan2
- POLR3A | c.917T>C p.I306T | Missense Mutation (SNP) | VAF 232/496 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- PRKAG1 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRS | c.947G>C p.S316T | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAPGEF2 | c.137_138dup p.G47Qfs*30 | Frame Shift Ins (INS) | VAF 53/176 reads (30%) | called by mutect2, pindel, varscan2
- RCBTB2 | c.815T>C p.L272S | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX6 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 154/161 reads (96%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SFI1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC44A5 | c.471+1G>A p.X157_splice | Splice Site (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- SPTBN5 | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SRSF6 | c.104del p.N35Mfs*21 | Frame Shift Del (DEL) | VAF 70/189 reads (37%) | called by mutect2, pindel, varscan2
- SULT1A2 | c.420C>G p.Y140* | Nonsense Mutation (SNP) | VAF 75/292 reads (26%) | called by muse, mutect2, varscan2
- TAOK2 | c.3290T>C p.F1097S | Missense Mutation (SNP) | VAF 134/216 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTC23L | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- VASH1 | c.353T>A p.V118D | Missense Mutation (SNP) | VAF 183/394 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- XPO6 | c.3134A>G p.E1045G | Missense Mutation (SNP) | VAF 208/337 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZNF628 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 106/231 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKR7A3 | c.441C>A p.A147= | Silent (SNP) | VAF 211/457 reads (46%) | called by muse, mutect2, varscan2
- ATG14 | c.1395C>T p.I465= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as rs766410608; called by muse, varscan2
- BAHCC1 | c.1884C>T p.D628= | Silent (SNP) | VAF 38/359 reads (11%) | catalogued as rs782221659, COSV100312006; called by muse, mutect2, varscan2
- CEP131 | c.744G>C p.T248= | Silent (SNP) | VAF 164/244 reads (67%) | called by muse, mutect2, varscan2
- DNAAF3 | c.1461C>T p.N487= (on ENST00000524407 / NM_001256715.2; = p.N534= on NM_178837.4) | Silent (SNP) | VAF 103/231 reads (45%) | called by muse, mutect2, varscan2
- FCGR2A | c.915G>C p.L305= (on ENST00000271450 / NM_001136219.3; = p.L304= on NM_021642.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 97/277 reads (35%) | called by muse, mutect2, varscan2
- FCRL4 | c.1018C>T p.L340= | Silent (SNP) | VAF 113/255 reads (44%) | catalogued as COSV99619210; called by muse, mutect2, varscan2
- KCND1 | c.1665C>T p.S555= | Silent (SNP) | VAF 177/192 reads (92%) | called by muse, mutect2, varscan2
- LMO7 | c.2883A>G p.V961= (on ENST00000357063; = p.V642= on NM_005358.5) | Silent (SNP) | VAF 144/376 reads (38%) | called by muse, mutect2, varscan2
- MUTYH | c.1410T>C p.A470= | Silent (SNP) | VAF 162/365 reads (44%) | called by muse, mutect2, varscan2
- PAQR9 | c.513C>G p.A171= | Silent (SNP) | VAF 137/301 reads (46%) | called by muse, mutect2, varscan2
- PNN | c.2091A>T p.S697= | Silent (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- SCO2 | c.297G>A p.V99= | Silent (SNP) | VAF 297/653 reads (45%) | catalogued as rs1316800374; called by muse, mutect2, varscan2
- SFXN3 | c.801G>T p.G267= | Silent (SNP) | VAF 151/331 reads (46%) | called by muse, mutect2, varscan2
- SLC34A2 | c.846T>G p.V282= | Silent (SNP) | VAF 100/242 reads (41%) | called by muse, mutect2, varscan2
- SLC44A3 | c.48T>A p.P16= | Silent (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- TTC13 | c.2487G>A p.K829= | Silent (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- ACAP2 | c.1011-19A>G | Intron (SNP) | VAF 77/164 reads (47%) | catalogued as rs1044241940; called by muse, mutect2, varscan2
- AMPD2 | c.719-30G>T | Intron (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-199G>A | Intron (SNP) | VAF 86/214 reads (40%) | called by muse, mutect2, varscan2
- ATF1 | c.*1_*5delinsA | 3'UTR (DEL) | VAF 21/67 reads (31%) | called by pindel, varscan2*
- FAM3A | c.127+400T>G | Intron (SNP) | VAF 33/35 reads (94%) | called by muse, mutect2, varscan2
- GCLM | c.192+27A>G | Intron (SNP) | VAF 89/227 reads (39%) | called by muse, mutect2, varscan2
- GTF2B | c.-39C>T | 5'UTR (SNP) | VAF 73/153 reads (48%) | catalogued as rs377183422, COSV100980513; called by muse, mutect2, varscan2
- MED24 | c.2624-79_2624-77del | Intron (DEL) | VAF 217/354 reads (61%) | called by mutect2, pindel, varscan2
- MIR1915 | chr10:21495606 T>C | 3'Flank (SNP) | VAF 202/439 reads (46%) | called by muse, mutect2, varscan2
- PCMTD1 | c.308-4313T>A | Intron (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- RABL6 | c.*442C>A | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, varscan2
- RBBP8 | c.2358-8del | Intron (DEL) | VAF 103/272 reads (38%) | called by mutect2, pindel, varscan2
- RBFOX1 | c.-9A>G | 5'UTR (SNP) | VAF 170/250 reads (68%) | catalogued as rs542039413; called by muse, mutect2, varscan2
- RCC1 | c.-187del | 5'UTR (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- RUSC1 | c.-87+292C>A | Intron (SNP) | VAF 94/184 reads (51%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.*15_*24del | 3'UTR (DEL) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- ST8SIA4 | c.798-4416A>C | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- TRIM4 | c.919+1061C>G | Intron (SNP) | VAF 80/179 reads (45%) | called by muse, mutect2, varscan2
- TSPAN2 | c.*64C>G | 3'UTR (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2
- TSPAN2 | c.*62T>C | 3'UTR (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2
- UBE2D3 | c.25-1901T>C | Intron (SNP) | VAF 64/204 reads (31%) | called by muse, mutect2, varscan2
